Somatic mutation profile of tumor specimen MMRF_1304_1_BM_CD138pos (aliquot MMRF_1304_1_BM_CD138pos_T1_KAS5U_L00338) from MMRF case MMRF_1304, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.0 years (26,307 days).
Specimen MMRF_1304_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e79b280c-243e-4c04-a97a-a7d76290e7ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1304_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1304_1_PB_Whole_C3_KAS5U_L00339; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/254b894d-dcc7-4963-95f4-d809f5827e2c

The open-access MAF lists 74 somatic variants for this specimen: 26 protein-altering or splice-affecting, 11 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 24, Missense Mutation 21, Silent 11, Intron 7, 5'UTR 4, Nonsense Mutation 3, 3'Flank 1, Splice Region 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DOCK4 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.195); catalogued as rs201403135, COSV70325719; called by muse, mutect2, varscan2
- GALNT12 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1204571302; called by muse, mutect2, varscan2
- IGHD3-22 | c.7C>G p.L3V | Missense Mutation (SNP) | VAF 10/12 reads (83%) | catalogued as rs569854973; called by muse, mutect2
- IGLL5 | c.166G>C p.V56L | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs531309531, COSV73250375, COSV73250928; called by muse, varscan2
- KCTD15 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1388792656; called by muse, mutect2, varscan2
- LINGO1 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV62438179; called by muse, mutect2
- MPDZ | c.1246G>A p.V416I | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs753084316, COSV100061128; called by muse, mutect2, varscan2
- PRELID1 | c.512-6C>T | Splice Region (SNP) | VAF 98/176 reads (56%) | catalogued as rs1487451630; called by muse, varscan2
- SLC2A10 | c.826C>A p.L276I | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.749); catalogued as rs760309737; called by muse, mutect2, varscan2
- TAF15 | c.350A>G p.D117G (on ENST00000605844 / NM_139215.3; = p.D114G on NM_003487.4) | Missense Mutation (SNP) | VAF 66/106 reads (62%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs755825241; called by muse, mutect2, varscan2
- TBX15 | c.14G>A p.R5K | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious, low confidence (0.02); catalogued as COSV104392401; called by muse, mutect2, varscan2
- CCN1 | c.1052A>T p.Q351L | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2
- DPYD | c.1258A>G p.N420D | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBF1 | c.1498C>T p.Q500* (on ENST00000586717; = p.Q514* on NM_001319193.1) | Nonsense Mutation (SNP) | VAF 10/104 reads (10%) | called by muse, mutect2
- ISL1 | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 16/124 reads (13%) | called by muse, mutect2, varscan2
- ITCH | c.973C>T p.Q325* (on ENST00000262650 / NM_001257137.3; = p.Q284* on NM_031483.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- KALRN | c.6764C>T p.P2255L (on ENST00000360013 / NM_001024660.4; = p.P558L on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- LCOR | c.2588_2593del p.G863_T865delinsA | In Frame Del (DEL) | VAF 27/77 reads (35%) | called by mutect2, pindel, varscan2
- NXPH1 | c.316A>G p.R106G | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PHYHIPL | c.883T>G p.F295V | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- PIGT | c.643T>C p.Y215H | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- POU5F2 | c.565A>C p.K189Q | Missense Mutation (SNP) | VAF 11/175 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- SNRPA1 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- TMEM255A | c.314G>A p.C105Y | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VPREB3 | c.112C>G p.L38V | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- WDR90 | c.4504T>A p.Y1502N | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DNAJC28 | c.603A>G p.E201= | Silent (SNP) | VAF 10/224 reads (4%) | catalogued as COSV58721499; called by muse, mutect2
- DNHD1 | c.10914A>G p.E3638= | Silent (SNP) | VAF 91/146 reads (62%) | called by muse, mutect2, varscan2
- EPB42 | c.732G>A p.K244= (on ENST00000441366 / NM_001114134.2; = p.K274= on NM_000119.3) | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as rs935830615; called by muse, mutect2, varscan2
- IGHV2-70 | c.165G>A p.V55= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as rs374197671; called by muse, varscan2
- KAT2B | c.720A>G p.E240= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs958704969; called by muse, mutect2
- KCNA4 | c.879T>C p.I293= | Silent (SNP) | VAF 52/89 reads (58%) | called by muse, mutect2, varscan2
- MPDZ | c.1791C>T p.D597= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs759799394, COSV100065011; called by muse, mutect2, varscan2
- PITPNM3 | c.1527G>A p.S509= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as rs758234075, COSV52599523; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC16A4 | c.481T>C p.L161= | Silent (SNP) | VAF 40/99 reads (40%) | catalogued as rs1046270396; called by muse, mutect2, varscan2
- TTN | c.79881A>T p.S26627= (on ENST00000591111; = p.S19203= on NM_003319.4) | Silent (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2, varscan2
- WDR81 | c.699G>A p.V233= | Silent (SNP) | VAF 32/114 reads (28%) | called by muse, mutect2, varscan2
- ABI3BP | c.*298G>A | 3'UTR (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2, varscan2
- ADD1 | c.*94A>T | 3'UTR (SNP) | VAF 56/136 reads (41%) | called by muse, mutect2, varscan2
- AEBP2 | c.*546A>T | 3'UTR (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2, varscan2
- AFF3 | c.*151T>C | 3'UTR (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2, varscan2
- ANK2 | c.*1009T>C | 3'UTR (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- CCDC141 | c.1899+2019A>C | Intron (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2, varscan2
- CD82 | c.261+61T>C | Intron (SNP) | VAF 5/86 reads (6%) | called by muse, mutect2
- CEP19 | c.-114A>C | 5'UTR (SNP) | VAF 26/99 reads (26%) | called by muse, mutect2, varscan2
- CKMT2 | c.1014+92A>C | Intron (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- CMSS1 | c.65-5357A>G | Intron (SNP) | VAF 27/100 reads (27%) | called by muse, mutect2
- COL4A6 | c.*282G>T | 3'UTR (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- CST9 | c.*1015A>G | 3'UTR (SNP) | VAF 23/45 reads (51%) | catalogued as rs1251917505; called by muse, mutect2, varscan2
- DAB2IP | c.*2607G>A | 3'UTR (SNP) | VAF 17/174 reads (10%) | called by muse, mutect2
- EI24 | c.189-410G>A | Intron (SNP) | VAF 6/14 reads (43%) | catalogued as rs545671683; called by muse, varscan2
- GALNT7 | c.*1625C>G | 3'UTR (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2, varscan2
- HDAC2 | c.*4780A>T | 3'UTR (SNP) | VAF 22/48 reads (46%) | catalogued as rs866769018; called by muse, varscan2
- HOOK2 | c.*28C>T | 3'UTR (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- HTR6 | c.-36A>G | 5'UTR (SNP) | VAF 5/104 reads (5%) | called by muse, mutect2
- LCOR | c.*952G>A | 3'UTR (SNP) | VAF 19/45 reads (42%) | called by muse, mutect2, varscan2
- MDK | c.*172A>G | 3'UTR (SNP) | VAF 50/293 reads (17%) | called by muse, mutect2, varscan2
- MEOX2 | c.*1072C>T | 3'UTR (SNP) | VAF 10/53 reads (19%) | catalogued as rs1293647844; called by muse, mutect2, varscan2
- NR3C1 | c.*511T>A | 3'UTR (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- NSRP1 | c.*34del | 3'UTR (DEL) | VAF 65/249 reads (26%) | called by mutect2, pindel, varscan2
- OR2A13P | n.119C>A | RNA (SNP) | VAF 16/64 reads (25%) | called by muse, varscan2
- PABPN1 | c.352-52C>T | Intron (SNP) | VAF 8/52 reads (15%) | catalogued as rs745756021; called by muse, mutect2, varscan2
- PCDH11X | c.*2720A>T | 3'UTR (SNP) | VAF 10/87 reads (11%) | called by muse, mutect2
- PGBD4 | c.*91A>C | 3'UTR (SNP) | VAF 66/150 reads (44%) | called by muse, varscan2
- PTEN | c.*429G>A | 3'UTR (SNP) | VAF 29/72 reads (40%) | catalogued as rs1423207931; called by muse, mutect2, varscan2
- RCL1 | c.-4G>A | 5'UTR (SNP) | VAF 75/142 reads (53%) | called by muse, mutect2, varscan2
- SLAMF1 | c.*58T>G | 3'UTR (SNP) | VAF 6/107 reads (6%) | called by muse, mutect2
- SLC44A1 | c.*1941G>A | 3'UTR (SNP) | VAF 5/73 reads (7%) | called by muse, mutect2
- SLC50A1 | c.159-33_159-25del | Intron (DEL) | VAF 4/45 reads (9%) | called by mutect2, pindel
- SNRNP27 | c.*734T>G | 3'UTR (SNP) | VAF 21/57 reads (37%) | called by muse, mutect2, varscan2
- SPAG9 | c.*1064A>G | 3'UTR (SNP) | VAF 39/70 reads (56%) | catalogued as rs1446490348; called by muse, mutect2, varscan2
- STC2 | c.*435C>T | 3'UTR (SNP) | VAF 54/197 reads (27%) | catalogued as rs1213630071; called by muse, mutect2, varscan2
- TMEM40 | chr3:12734365 del AGGATGGCTCGG | 3'Flank (DEL) | VAF 7/93 reads (8%) | called by mutect2, pindel
- TOPAZ1 | c.-29G>A | 5'UTR (SNP) | VAF 38/56 reads (68%) | called by muse, mutect2, varscan2
